TCGA case TCGA-A2-A04W — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adnexal and Skin Appendage Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00807dae-9f4a-4fd1-aac2-82eb11bf2afb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Apocrine adenocarcinoma: ICD-O-3 morphology code: 8401/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 50.2 years (18,345 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1mi; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 19; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 58 days; Days to treatment end: 100 days; Number of cycles: 4; Treatment dose: 4,400 mg; Prescribed dose: 1100; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 58 days; Days to treatment end: 100 days; Number of cycles: 4; Treatment dose: 440 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 114 days; Days to treatment end: 191 days; Number of cycles: 12; Treatment dose: 1,768 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 198 days; Days to treatment end: 352 days; Number of cycles: 18; Treatment dose: 4,187 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Bisphosphonate Therapy; Therapeutic agents: Zoledronic Acid; Treatment intent type: Adjuvant; Days to treatment start: 1,023 days (2.8 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 4; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,918 days (5.3 years); Disease response: Tumor Free.
- Days to follow up: 1,948 days (5.3 years); Disease response: Tumor Free.
- Days to follow up: 3,102 days (8.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 3.2; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Positive.
- ERBB2 amplification (FISH): Positive.
- ESR1 (IHC): Negative; Test value range: <10%.
- PGR (IHC): Negative; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A04W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 420 mg.
  Slide TCGA-A2-A04W-01A-03-BSC: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 55; Percent normal cells: 39; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A04W-01A-03-TSC: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A04W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A04W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 3.2; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Apocrine; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 3: Regimen number: 3; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Regimen number: 4; Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 5: Regimen number: 5; Pharmaceutical therapy drug name: Zometa.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,102 days; disease-specific survival: no event (censored), 3,102 days; disease-free interval: no event (censored), 3,102 days; progression-free interval: no event (censored), 3,102 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A04W-01A-31D-A111-01): tumor purity 0.3, ploidy 3.14, whole-genome doublings 1.
